Surgical pathology report (de-identified scan), TCGA case TCGA-DC-6156, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-6156-01A (Primary Tumor).

[page 1 of 4]
[REDACTED] [REDACTED]
[REDACTED] [REDACTED]
[REDACTED] [REDACTED]
[REDACTED] [REDACTED]
[REDACTED] [REDACTED]
[REDACTED] [REDACTED]

** Continued on next page **

[page 2 of 4]
Free of tumor
Surgical Margins:
Free of tumor
0.15 cm between deepest tumor portion and deep (radial soft
tissue) margin
Polyps/Mucosa Dysplasia (away from the carcinoma):
Not Identified
Non-Neoplastic Bowel:
Unremarkable
Lymph Nodes:
Number with metastasis: 7
Total number examined: 22
Tumor deposits in pericorectal soft tissue:
Not Identified
Tumor Staging (AJCC [REDACTED])
pT4a (Tumor penetrates to the surface of the visceral peritoneum)
Lymph Node Stage (AJCC [REDACTED])
N2b (Metastasis in seven or more regional lymph nodes)

2. COLON, PROXIMAL RING; EXCISION:
-BENIGN COLONIC TISSUE.
3. COLON, DISTAL RING; EXCISION:
-BENIGN COLONIC TISSUE.
4. HERNIA SAC, UMBILICAL; HERNIORRHAPHY:
-METASTATIC ADENOCARCINOMA, MODERATELY DIFFERENTIATED, CONSISTENT WITH
COLONIC PRIMARY.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh and is labeled "sigmoid and upper
rectum". It consists of a rectosigmoid colon that measure 20 x 12 x 8 cm.
The radial resection margin is inked black and the serosa is inked blue.
The serosa shows a large area of retraction 7 cm from the distal margin.
The specimen is opened to reveal a circumferential, constricting tumor that
is located 11 cm from the proximal margin and 7 cm from the distal margin.
The tumor measures 5.5 cm in length and 3.5 cm in width. Serial sectioning
reveals tumor invasion to a depth of 2.5 cm, which is 0.5 cm from the
closest radial margin. The remaining mucosa shows no abnormality.
Pericolic and peri-rectal adipose tissue is submitted for lymph node
dissection, and all possible nodes are submitted. Also received is a

** Continued on next page **

[page 3 of 4]
separate portion of omentum with dimensions of 15 x 9 x 2 cm. The omentum is diffusely involved by firm white tumor. Representative sections are submitted. TPS is submitted.

Summary of sections:

PM - proximal margin
DM - distal margin
TS- tumor to serosa
TR- tumor to radial margin
T - tumor
U - uninvolved mucosa
O- omentum
LN - lymph nodes
BLN - bisected lymph node

2). The specimen is received in formalin, labeled "Proximal ring" and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a white plastic piece is noted. A ring of pink tan soft tissue is attached measuring 2 x 1.5 x 1 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U undesignated

3). The specimen is received in formalin, labeled "Distal ring" and consists of a ring of pink tan soft tissue measuring 2.2 x 2 x 1 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U undesignated

4). The specimen is received in formalin, labeled "Umbilical hernia sac" and consists of a pink tan fibromembranous tissue measuring 5.5 x 3.5 x 0.6 cm. Serial sectioning reveals a white-tan firm mass measuring 1.1 x 1.0 x 0.7 cm. Representative sections are submitted.

Summary of sections:

M - mass
RS - remaining specimen, representatively

** Continued on next page **

[page 4 of 4]
Summary of Sections:

Part 1: SP: SIGMOID AND UPPER RECTUM; RESECTION

Block	Sect.	Site	PCs
1		BLN	2
1		DM	1
8		LN	23
2		O	2
1		PM	1
3		T	3
2		TR	2
2		TS	2

Part 2: SP: Proximal ring

Block	Sect.	Site	PCs
1		U	1

Part 3: SP: Distal ring

Block	Sect.	Site	PCs
1		U	1

Part 4: SP: Umbilical hernia sac

Block	Sect.	Site	PCs
2		M	4
2		RS	4

** End of Report **

Source: NCI Genomic Data Commons file 13413120-b265-4494-8b47-f81d4ae8fb31 (TCGA-DC-6156.08D31ED7-5E5F-4874-A5A5-8D4EF1D0799A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).